Somatic mutation profile of tumor specimen TARGET-10-PAPFHR-09A (aliquot TARGET-10-PAPFHR-09A-01D) from TARGET case TARGET-10-PAPFHR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (874 days).
Specimen TARGET-10-PAPFHR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18dfb70f-90a4-40d0-8f34-9de6f8d6e263.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPFHR-14A (Bone Marrow Normal), aliquot TARGET-10-PAPFHR-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dda1c7c-aebe-4397-931a-7a748f832d47

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDHAC1 | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV53846246, COSV53852350; called by muse, mutect2
- SRPX2 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1181884783, COSV65933849; called by muse, mutect2, varscan2
- ITPRIPL2 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- SUPT6H | c.3389T>C p.L1130P | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF850 | c.2830C>T p.H944Y | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- AC009533.1 | n.1550C>T | RNA (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- HOXA10 | c.*12G>T | 3'UTR (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- MNDA | c.265+21C>A | Intron (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
